Somatic mutation profile of tumor specimen C3L-01833-01 (aliquot CPT0100010009) from CPTAC case C3L-01833, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Age at diagnosis: 62.8 years (22,921 days).
Specimen C3L-01833-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cd67e080-1a23-451b-b1e0-3a31d1623b4e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01833-32 (Blood Derived Normal), aliquot CPT0100050002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/17313de9-2f04-469e-9338-5f593521f918

The open-access MAF lists 115 somatic variants for this specimen: 77 protein-altering or splice-affecting, 21 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, Silent 21, RNA 6, Intron 6, Nonsense Mutation 5, Splice Region 5, 3'UTR 4, Frame Shift Del 3, Splice Site 2, In Frame Del 1, Nonstop Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 167/450 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- DMD | c.1615C>T p.R539* | Nonsense Mutation (SNP) | VAF 141/355 reads (40%) | catalogued as rs398123865, CM080213; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FGFR2 | c.755C>G p.S252W | Missense Mutation (SNP) | VAF 45/131 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs79184941, CM950458, CM970526, COSV60638319; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TMEM107 | c.*671G>A | 3'UTR (SNP) | VAF 62/182 reads (34%) | catalogued as rs886039784; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADGRB3 | c.806C>T p.S269F | Missense Mutation (SNP) | VAF 54/157 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as rs971919185; called by muse, mutect2, varscan2
- ARID1A | c.5009G>A p.W1670* | Nonsense Mutation (SNP) | VAF 83/219 reads (38%) | catalogued as COSV61373865; called by muse, mutect2, varscan2
- BCLAF1 | c.1551G>C p.K517N | Missense Mutation (SNP) | VAF 78/241 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV62142015; called by muse, mutect2, varscan2
- CDH15 | c.663+3G>A | Splice Region (SNP) | VAF 105/249 reads (42%) | catalogued as rs1248105107; called by muse, mutect2, varscan2
- CDH22 | c.1057G>A p.V353M | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.89); catalogued as COSV64836396; called by muse, mutect2, varscan2
- CEP250 | c.1556G>A p.R519Q | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.789); catalogued as rs115893489; called by muse, mutect2, varscan2
- CLCNKA | c.1981C>T p.R661W | Missense Mutation (SNP) | VAF 100/229 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.035); catalogued as rs757979867, COSV58891626; called by muse, mutect2, varscan2
- CNTNAP4 | c.1882G>A p.E628K | Missense Mutation (SNP) | VAF 48/152 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.107); catalogued as rs1479349316, COSV56686972, COSV56693705; called by muse, mutect2, varscan2
- COL22A1 | c.3186G>A p.P1062= | Splice Region (SNP) | VAF 59/149 reads (40%) | catalogued as rs371517268; called by muse, mutect2, varscan2
- CTCF | c.349C>T p.Q117* | Nonsense Mutation (SNP) | VAF 91/236 reads (39%) | catalogued as COSV50461476; called by muse, mutect2, varscan2
- DCHS1 | c.8612G>A p.R2871Q | Missense Mutation (SNP) | VAF 159/363 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.644); catalogued as rs148710242; called by muse, mutect2, varscan2
- DLGAP2 | c.2202+1G>A p.X734_splice | Splice Site (SNP) | VAF 62/198 reads (31%) | catalogued as rs767210397, COSV70104104; called by muse, mutect2, varscan2
- EDRF1 | c.3330A>G p.I1110M (on ENST00000356792 / NM_001202438.2; = p.I1076M on NM_015608.2) | Missense Mutation (SNP) | VAF 120/370 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as rs771620062; called by muse, mutect2, varscan2
- EOGT | c.1534G>A p.V512I (on ENST00000383701 / NM_001278689.2; = p.V428I on NM_173654.3) | Missense Mutation (SNP) | VAF 77/216 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.085); catalogued as rs562651560; called by muse, varscan2
- FAM83B | c.1622G>T p.R541L | Missense Mutation (SNP) | VAF 28/213 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775965658, COSV60922593; called by muse, mutect2, varscan2
- FSD1L | c.479C>T p.S160L | Missense Mutation (SNP) | VAF 60/144 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV66004331; called by muse, mutect2, varscan2
- GRIA1 | c.622C>T p.R208C | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs146865938; called by muse, mutect2, varscan2
- GRIN2A | c.2884G>T p.E962* | Nonsense Mutation (SNP) | VAF 241/660 reads (37%) | catalogued as rs765370528, COSV58022947, COSV58048177; called by muse, mutect2, varscan2
- GTF3C1 | c.374A>G p.N125S | Missense Mutation (SNP) | VAF 164/430 reads (38%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs756385820; called by muse, mutect2, varscan2
- HSP90AA1 | c.1325C>G p.S442C | Missense Mutation (SNP) | VAF 105/308 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs767150173; called by muse, mutect2, varscan2
- KRTAP10-7 | c.456G>T p.Q152H | Missense Mutation (SNP) | VAF 182/551 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.481); catalogued as rs781844967, COSV100170144; called by muse, mutect2, varscan2
- LRP2 | c.974C>T p.P325L | Missense Mutation (SNP) | VAF 183/504 reads (36%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.999); catalogued as rs79877455; called by muse, mutect2, varscan2
- MARCHF8 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs200386692, COSV60574344, COSV60575147; called by muse, mutect2, varscan2
- MCAM | c.1885G>A p.G629S | Missense Mutation (SNP) | VAF 88/205 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.926); catalogued as rs2276081; called by muse, mutect2, varscan2
- MEX3D | c.1154C>T p.T385M | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.439); catalogued as rs754530692; called by muse, mutect2, varscan2
- MKI67 | c.466C>T p.Q156* | Nonsense Mutation (SNP) | VAF 66/173 reads (38%) | catalogued as COSV64075930; called by muse, mutect2, varscan2
- MKI67 | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 87/242 reads (36%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.446); catalogued as rs763797888; called by muse, mutect2, varscan2
- MUC5B | c.6647C>T p.S2216L | Missense Mutation (SNP) | VAF 101/626 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.088); catalogued as rs267602740; called by muse, mutect2, varscan2
- NR3C2 | c.2511-1G>A p.X837_splice | Splice Site (SNP) | VAF 98/283 reads (35%) | catalogued as COSV60986840; called by muse, mutect2, varscan2
- PHF3 | c.2540A>C p.E847A | Missense Mutation (SNP) | VAF 50/109 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as rs1223048675; called by muse, mutect2, varscan2
- PIDD1 | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 87/198 reads (44%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs144504693; called by muse, mutect2, varscan2
- PTEN | c.955_958del p.T319* | Frame Shift Del (DEL) | VAF 60/166 reads (36%) | catalogued as rs146650273; called by pindel, varscan2
- SCN3A | c.847A>G p.S283G | Missense Mutation (SNP) | VAF 156/411 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs369051978; called by muse, mutect2, varscan2
- SLC22A18 | c.259G>A p.G87R | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs756886549; called by muse, mutect2, varscan2
- TMEM177 | c.667C>G p.L223V | Missense Mutation (SNP) | VAF 84/233 reads (36%) | SIFT tolerated (0.76); PolyPhen benign (0.147); catalogued as COSV55608552; called by muse, mutect2, varscan2
- TMPRSS5 | c.1288G>A p.A430T | Missense Mutation (SNP) | VAF 51/127 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375329875; called by muse, mutect2, varscan2
- TRIOBP | c.5899G>A p.D1967N (on ENST00000644935 / NM_001039141.3; = p.D254N on NM_007032.5) | Missense Mutation (SNP) | VAF 69/162 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.617); catalogued as COSV58525858; called by muse, mutect2, varscan2
- UBE2R2 | c.180G>A p.A60= | Splice Region (SNP) | VAF 37/129 reads (29%) | catalogued as rs767478191, COSV54291188; called by muse, mutect2, varscan2
- ZCCHC12 | c.211G>A p.V71I | Missense Mutation (SNP) | VAF 102/242 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as rs946147207, COSV59570945; called by muse, mutect2, varscan2
- ZFP92 | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 88/245 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1556975031; called by muse, mutect2, varscan2
- ZNF609 | c.*5G>A | Splice Region (SNP) | VAF 48/124 reads (39%) | catalogued as rs1373276966; called by muse, mutect2, varscan2
- ABCA13 | c.12614G>A p.R4205H | Missense Mutation (SNP) | VAF 48/105 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- ARL8A | c.388A>G p.N130D | Missense Mutation (SNP) | VAF 197/360 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C2orf78 | c.2086G>A p.G696S | Missense Mutation (SNP) | VAF 119/310 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CCDC168 | c.10769G>A p.S3590N | Missense Mutation (SNP) | VAF 65/172 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CREB3 | c.234C>G p.D78E | Missense Mutation (SNP) | VAF 118/310 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.49); called by muse, mutect2, varscan2
- CTCF | c.1004G>A p.G335E | Missense Mutation (SNP) | VAF 72/243 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DCLK3 | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- EFNB1 | c.461G>T p.R154L | Missense Mutation (SNP) | VAF 130/359 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- FOXL1 | c.581C>T p.S194L | Missense Mutation (SNP) | VAF 56/141 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- HIVEP2 | c.4785del p.E1596Rfs*52 | Frame Shift Del (DEL) | VAF 126/346 reads (36%) | called by mutect2, pindel, varscan2
- KIF1B | c.2790G>C p.E930D (on ENST00000377086 / NM_001365952.1; = p.E884D on NM_015074.3) | Missense Mutation (SNP) | VAF 197/534 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIF20A | c.2236A>C p.T746P | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- MAPKAPK3 | c.34_46delinsA p.P12_P16delinsT | In Frame Del (DEL) | VAF 42/113 reads (37%) | called by pindel, varscan2*
- MED23 | c.2607+5G>C | Splice Region (SNP) | VAF 55/178 reads (31%) | called by muse, mutect2, varscan2
- MICALL1 | c.2287C>G p.R763G | Missense Mutation (SNP) | VAF 11/245 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- NR2E1 | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 164/467 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- NUMB | c.1009G>A p.A337T (on ENST00000355058; = p.A326T on NM_003744.5) | Missense Mutation (SNP) | VAF 67/201 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NUP98 | c.2302G>T p.G768C | Missense Mutation (SNP) | VAF 51/128 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTEN | c.986_1001del p.N329Tfs*10 | Frame Shift Del (DEL) | VAF 49/142 reads (35%) | called by pindel, varscan2
- QARS1 | c.2206A>G p.K736E | Missense Mutation (SNP) | VAF 13/328 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.018); called by muse, mutect2
- RIN3 | c.1005G>T p.Q335H | Missense Mutation (SNP) | VAF 78/194 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- SCAF11 | c.37G>T p.D13Y | Missense Mutation (SNP) | VAF 48/169 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SERHL2 | c.856C>T p.H286Y | Missense Mutation (SNP) | VAF 72/146 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- SERHL2 | c.909C>G p.F303L | Missense Mutation (SNP) | VAF 90/200 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, varscan2
- SNTG1 | c.1474C>A p.P492T | Missense Mutation (SNP) | VAF 22/157 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- SP9 | c.427G>C p.D143H | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM199 | c.405C>A p.D135E | Missense Mutation (SNP) | VAF 84/201 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TMEM225B | c.242C>G p.S81C | Missense Mutation (SNP) | VAF 70/173 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- TRIP4 | c.1468C>G p.L490V | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2
- TTLL12 | c.175G>C p.E59Q | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.5); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- VAMP2 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZFHX4 | c.2317G>A p.D773N | Missense Mutation (SNP) | VAF 90/280 reads (32%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZNF527 | c.1829G>C p.*610Sext*2 | Nonstop Mutation (SNP) | VAF 25/53 reads (47%) | called by muse, mutect2, varscan2
- AC097637.1 | c.105C>T p.T35= | Silent (SNP) | VAF 63/162 reads (39%) | called by muse, mutect2, varscan2
- ACOX3 | c.1962G>T p.P654= | Silent (SNP) | VAF 74/199 reads (37%) | catalogued as rs757529325; called by muse, mutect2, varscan2
- ADAM33 | c.1485T>C p.C495= | Silent (SNP) | VAF 58/165 reads (35%) | catalogued as rs578045242; called by muse, mutect2, varscan2
- CDH15 | c.513G>A p.V171= | Silent (SNP) | VAF 95/264 reads (36%) | called by muse, mutect2, varscan2
- CFAP77 | c.375C>T p.I125= | Silent (SNP) | VAF 49/142 reads (35%) | catalogued as COSV100546121; called by muse, mutect2, varscan2
- COL6A2 | c.2361G>A p.T787= | Silent (SNP) | VAF 109/268 reads (41%) | catalogued as rs566966690; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- CTNND2 | c.1338G>A p.P446= | Silent (SNP) | VAF 65/164 reads (40%) | catalogued as rs780920780, COSV58876426; called by muse, mutect2, varscan2
- FAAP100 | c.510C>T p.I170= | Silent (SNP) | VAF 66/177 reads (37%) | catalogued as rs746821415, COSV59883890; called by muse, mutect2, varscan2
- GUCY1A1 | c.1449C>G p.L483= | Silent (SNP) | VAF 96/323 reads (30%) | called by muse, mutect2, varscan2
- HSPG2 | c.1716G>A p.Q572= | Silent (SNP) | VAF 103/261 reads (39%) | called by muse, mutect2, varscan2
- KIF25 | c.819C>T p.S273= | Silent (SNP) | VAF 55/119 reads (46%) | catalogued as rs138836160; called by muse, mutect2, varscan2
- MAGEA12 | c.735G>T p.L245= | Silent (SNP) | VAF 171/461 reads (37%) | catalogued as rs1218682856, COSV63294872; called by muse, mutect2, varscan2
- NUAK1 | c.1191C>G p.P397= | Silent (SNP) | VAF 106/287 reads (37%) | called by muse, mutect2, varscan2
- OR5J2 | c.375C>T p.A125= | Silent (SNP) | VAF 92/216 reads (43%) | called by muse, mutect2, varscan2
- PCDH17 | c.1296C>T p.R432= | Silent (SNP) | VAF 54/381 reads (14%) | catalogued as COSV64972762; called by muse, mutect2, varscan2
- SHROOM4 | c.2658C>T p.C886= | Silent (SNP) | VAF 210/562 reads (37%) | called by muse, mutect2, varscan2
- SLC4A5 | c.2514C>T p.P838= | Silent (SNP) | VAF 61/188 reads (32%) | catalogued as rs373675468; called by muse, mutect2, varscan2
- SORD | c.927G>T p.S309= | Silent (SNP) | VAF 22/88 reads (25%) | called by muse, mutect2
- SPATA2L | c.195C>G p.A65= | Silent (SNP) | VAF 50/123 reads (41%) | called by muse, mutect2, varscan2
- VWA8 | c.2991T>C p.S997= | Silent (SNP) | VAF 68/172 reads (40%) | called by muse, mutect2, varscan2
- ZNF385D | c.51G>A p.P17= | Silent (SNP) | VAF 38/119 reads (32%) | catalogued as rs769275058; called by muse, mutect2, varscan2
- ADAM6 | n.1514G>A | RNA (SNP) | VAF 90/262 reads (34%) | catalogued as rs1391085882; called by muse, mutect2, varscan2
- AL353753.1 | n.400C>T | RNA (SNP) | VAF 27/52 reads (52%) | catalogued as rs1367160224; called by muse, mutect2, varscan2
- ANXA2P2 | n.921C>G | RNA (SNP) | VAF 164/507 reads (32%) | catalogued as rs1407271472; called by muse, mutect2, varscan2
- DLG2 | c.1978+851C>T | Intron (SNP) | VAF 81/246 reads (33%) | catalogued as rs772124362; called by muse, mutect2, varscan2
- GYPA | c.136+35C>T | Intron (SNP) | VAF 78/196 reads (40%) | catalogued as rs753888144; called by muse, mutect2, varscan2
- NRG1 | c.502+31282A>T | Intron (SNP) | VAF 135/333 reads (41%) | called by muse, mutect2, varscan2
- OR3A4P | n.1174C>T | RNA (SNP) | VAF 74/196 reads (38%) | called by muse, mutect2, varscan2
- PHKA2 | c.*41G>A | 3'UTR (SNP) | VAF 150/379 reads (40%) | catalogued as rs375034922; called by muse, mutect2, varscan2
- PPP1R14D | c.256-1019C>T | Intron (SNP) | VAF 16/38 reads (42%) | called by muse, mutect2, varscan2
- SATL1 | c.-375G>C | 5'UTR (SNP) | VAF 136/384 reads (35%) | called by muse, mutect2, varscan2
- SLC13A5 | c.369-37G>T | Intron (SNP) | VAF 46/111 reads (41%) | called by muse, mutect2, varscan2
- TSNARE1 | c.1446+3196C>T | Intron (SNP) | VAF 19/58 reads (33%) | catalogued as rs760139685; called by muse, mutect2, varscan2
- UGT2B27P | n.1215G>A | RNA (SNP) | VAF 118/303 reads (39%) | catalogued as rs541788918; called by muse, mutect2, varscan2
- XIAP | c.*5025A>G | 3'UTR (SNP) | VAF 13/116 reads (11%) | called by muse, mutect2, varscan2
- ZNF322P1 | n.115G>C | RNA (SNP) | VAF 102/311 reads (33%) | called by muse, mutect2, varscan2
- ZNF827 | c.*61G>C | 3'UTR (SNP) | VAF 37/91 reads (41%) | catalogued as rs1488330261; called by muse, mutect2, varscan2
